Somatic mutation profile of tumor specimen 0DAZOI from CCDI case PBBKTB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.0 years (3,282 days).
Specimen 0DAZOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eeec82ef-4d4b-478f-a911-9b37b6170db4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAZOJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c3b1070-68c9-46d8-877e-49db58f1050f

The open-access MAF lists 99 somatic variants for this specimen: 64 protein-altering or splice-affecting, 20 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 20, Intron 9, Nonsense Mutation 8, 3'UTR 3, Splice Region 2, In Frame Del 1, RNA 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 414/895 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906589, CM091421, COSV55115990, COSV55115998; ClinVar: likely pathogenic / other; called by muse, mutect2, varscan2
- CDH23 | c.6442G>A p.D2148N | Missense Mutation (SNP) | VAF 146/425 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs111033271, CM021546; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRG7 | c.1092C>G p.D364E | Missense Mutation (SNP) | VAF 123/414 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56297463; called by muse, mutect2, varscan2
- ARHGEF38 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 193/430 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV99486214; called by muse, mutect2, varscan2
- CACNA1C | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 131/735 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.945); catalogued as rs762091177, COSV59753261; called by muse, mutect2, varscan2
- CFAP47 | c.2324A>G p.N775S | Missense Mutation (SNP) | VAF 183/430 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52888955; called by muse, mutect2, varscan2
- DCSTAMP | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 271/1115 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV52576915; called by muse, mutect2, varscan2
- DEFB113 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as COSV100435474; called by muse, mutect2, varscan2
- DOCK2 | c.5086C>T p.R1696W | Missense Mutation (SNP) | VAF 169/628 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs980056604, COSV56944050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFT52 | c.706G>T p.V236F | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.393); catalogued as rs1223821636; called by muse, varscan2
- ITGA1 | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 126/385 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50896530; called by muse, mutect2, varscan2
- KCNK10 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs747254595, COSV56653095; called by muse, mutect2, varscan2
- OR2A14 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 70/303 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs1481069147, COSV68718411; called by muse, mutect2, varscan2
- PANK3 | c.973C>G p.R325G | Missense Mutation (SNP) | VAF 126/439 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53323877; called by muse, mutect2, varscan2
- PCDH17 | c.2565G>A p.Q855= | Splice Region (SNP) | VAF 82/214 reads (38%) | catalogued as COSV64979261; called by muse, mutect2, varscan2
- PLSCR5 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 151/535 reads (28%) | catalogued as rs371042953; called by muse, mutect2, varscan2
- RAB34 | c.146+3G>A | Splice Region (SNP) | VAF 129/555 reads (23%) | catalogued as rs1567736160; called by muse, mutect2, varscan2
- TAF5L | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 159/398 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs921203462; called by muse, mutect2, varscan2
- TGIF2LX | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 126/260 reads (48%) | catalogued as COSV52213220; called by muse, mutect2, varscan2
- TLE1 | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 152/356 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64720720; called by muse, mutect2, varscan2
- TMEM71 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 152/765 reads (20%) | catalogued as rs762484420, COSV100785481; called by muse, mutect2, varscan2
- TNRC18 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 113/385 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776348892, COSV68166748; called by muse, mutect2, varscan2
- TRIM22 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs553638122, COSV101181181; called by muse, mutect2, varscan2
- TSHZ2 | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 181/571 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100296431; called by muse, mutect2, varscan2
- ARL6 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 125/396 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRX | c.6126G>T p.Q2042H | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- C16orf46 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 242/492 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CABS1 | c.804T>G p.F268L | Missense Mutation (SNP) | VAF 135/337 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CATSPERZ | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 35/737 reads (5%) | called by muse, mutect2
- CDC73 | c.558A>T p.K186N | Missense Mutation (SNP) | VAF 165/397 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CDCA2 | c.91A>T p.K31* | Nonsense Mutation (SNP) | VAF 99/412 reads (24%) | called by muse, mutect2, varscan2
- CDK13 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 30/634 reads (5%) | called by muse, mutect2
- CFAP54 | c.8549T>A p.V2850E | Missense Mutation (SNP) | VAF 166/870 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CHSY1 | c.1913C>T p.T638I | Missense Mutation (SNP) | VAF 235/537 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DAW1 | c.986T>A p.I329N | Missense Mutation (SNP) | VAF 137/612 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- ESYT2 | c.1163G>T p.R388M (on ENST00000613624; = p.R312M on NM_020728.3) | Missense Mutation (SNP) | VAF 118/500 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FANCB | c.1979T>C p.F660S | Missense Mutation (SNP) | VAF 165/454 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- GABRB2 | c.1418A>T p.Q473L (on ENST00000274547; = p.Q435L on NM_000813.3) | Missense Mutation (SNP) | VAF 163/549 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GCC1 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 143/498 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPN3 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 216/654 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- GPR83 | c.358A>C p.I120L | Missense Mutation (SNP) | VAF 179/631 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ITGA2 | c.2368G>C p.G790R | Missense Mutation (SNP) | VAF 165/645 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MGAM2 | c.6076G>C p.A2026P | Missense Mutation (SNP) | VAF 32/727 reads (4%) | SIFT tolerated, low confidence (0.81); called by muse, mutect2
- MUC17 | c.9369C>A p.S3123R | Missense Mutation (SNP) | VAF 193/869 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MUC3A | c.7606G>A p.E2536K | Missense Mutation (SNP) | VAF 178/780 reads (23%) | SIFT deleterious, low confidence (0.02); called by muse, varscan2
- MYO1D | c.258C>A p.Y86* | Nonsense Mutation (SNP) | VAF 32/1002 reads (3%) | called by muse, mutect2
- NDRG1 | c.1141G>C p.A381P | Missense Mutation (SNP) | VAF 175/718 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5K1 | c.457A>T p.N153Y | Missense Mutation (SNP) | VAF 185/704 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- P2RY13 | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 237/751 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PFKL | c.2069T>A p.L690Q | Missense Mutation (SNP) | VAF 151/352 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- REELD1 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 116/261 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- REXO4 | c.832A>C p.K278Q | Missense Mutation (SNP) | VAF 157/351 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- RPRD2 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 64/539 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RS1 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- SLC1A3 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 110/353 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- SLFN14 | c.463T>G p.F155V | Missense Mutation (SNP) | VAF 21/657 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2
- SOHLH2 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 118/258 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SPDYE1 | c.382_384del p.E128del | In Frame Del (DEL) | VAF 33/102 reads (32%) | called by pindel, varscan2
- SRCAP | c.8767C>T p.P2923S | Missense Mutation (SNP) | VAF 106/202 reads (52%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRGAP1 | c.269A>T p.D90V | Missense Mutation (SNP) | VAF 169/557 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- SRRT | c.1493G>T p.R498M | Missense Mutation (SNP) | VAF 176/609 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- TNRC18 | c.5939C>T p.P1980L | Missense Mutation (SNP) | VAF 137/518 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF559 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 21/365 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- ZSCAN1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ABCA13 | c.7230G>A p.G2410= | Silent (SNP) | VAF 154/465 reads (33%) | catalogued as COSV71284587; called by muse, mutect2, varscan2
- ABHD1 | c.180C>T p.T60= | Silent (SNP) | VAF 24/826 reads (3%) | catalogued as rs896129474, COSV53206346; called by muse, mutect2
- CDCA2 | c.90G>A p.G30= | Silent (SNP) | VAF 98/410 reads (24%) | catalogued as rs1044975602; called by muse, mutect2, varscan2
- CLDN7 | c.366A>G p.G122= | Silent (SNP) | VAF 252/831 reads (30%) | called by muse, mutect2, varscan2
- COL20A1 | c.1830G>A p.S610= | Silent (SNP) | VAF 107/373 reads (29%) | catalogued as rs756932170; called by muse, mutect2, varscan2
- DDN | c.879C>G p.L293= | Silent (SNP) | VAF 123/753 reads (16%) | called by muse, mutect2, varscan2
- DUSP6 | c.708C>A p.I236= | Silent (SNP) | VAF 121/797 reads (15%) | called by muse, mutect2, varscan2
- FAT2 | c.9009C>T p.D3003= | Silent (SNP) | VAF 244/878 reads (28%) | catalogued as rs756285145, COSV55820540, COSV99941729; called by muse, mutect2, varscan2
- GGA1 | c.1287C>G p.T429= | Silent (SNP) | VAF 151/370 reads (41%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.417C>T p.G139= | Silent (SNP) | VAF 118/293 reads (40%) | called by muse, mutect2, varscan2
- MORC3 | c.2451C>T p.D817= | Silent (SNP) | VAF 169/401 reads (42%) | catalogued as rs376316188; called by muse, mutect2, varscan2
- MXRA5 | c.6267C>A p.I2089= | Silent (SNP) | VAF 117/231 reads (51%) | catalogued as rs1165717741; called by muse, mutect2, varscan2
- PAPPA2 | c.1323T>C p.S441= | Silent (SNP) | VAF 227/581 reads (39%) | called by muse, mutect2, varscan2
- PLD2 | c.2232G>T p.L744= | Silent (SNP) | VAF 132/367 reads (36%) | called by muse, mutect2, varscan2
- SCN11A | c.1794T>C p.H598= | Silent (SNP) | VAF 160/556 reads (29%) | called by muse, mutect2, varscan2
- SLC4A7 | c.234A>G p.K78= | Silent (SNP) | VAF 128/444 reads (29%) | called by muse, mutect2, varscan2
- SLC8A3 | c.150G>A p.G50= | Silent (SNP) | VAF 107/218 reads (49%) | called by muse, mutect2, varscan2
- SLITRK4 | c.1362G>T p.L454= | Silent (SNP) | VAF 152/325 reads (47%) | called by muse, mutect2, varscan2
- STK11IP | c.1734G>A p.E578= | Silent (SNP) | VAF 209/904 reads (23%) | catalogued as rs1357049847; called by muse, mutect2, varscan2
- TYMS | c.165C>T p.T55= | Silent (SNP) | VAF 80/192 reads (42%) | called by muse, mutect2, varscan2
- AC091770.1 | n.426G>C | RNA (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- ACLY | c.-57G>A | 5'UTR (SNP) | VAF 204/781 reads (26%) | catalogued as rs1555634963; called by muse, mutect2, varscan2
- ATF7IP | c.3280+14C>A | Intron (SNP) | VAF 82/559 reads (15%) | called by muse, mutect2, varscan2
- C6 | c.588-71T>C | Intron (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- C9orf40 | c.*15G>A | 3'UTR (SNP) | VAF 90/223 reads (40%) | called by muse, mutect2, varscan2
- CHD8 | c.2024+85T>C | Intron (SNP) | VAF 66/122 reads (54%) | called by muse, mutect2
- CLEC4D | c.*36A>T | 3'UTR (SNP) | VAF 85/441 reads (19%) | called by muse, mutect2, varscan2
- FLII | c.679+82G>A | Intron (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- GSAP | chr7:77416856 T>A | 5'Flank (SNP) | VAF 66/235 reads (28%) | called by muse, mutect2, varscan2
- MARK2 | c.*30C>A | 3'UTR (SNP) | VAF 97/341 reads (28%) | called by muse, mutect2, varscan2
- NCKAP1L | c.941+85C>A | Intron (SNP) | VAF 71/184 reads (39%) | called by muse, mutect2, varscan2
- NPRL3 | c.1162-24A>C | Intron (SNP) | VAF 13/190 reads (7%) | called by muse, mutect2
- PROCA1 | c.78+668C>T | Intron (SNP) | VAF 182/752 reads (24%) | catalogued as rs1455141025; called by muse, mutect2, varscan2
- SLCO1C1 | c.1916+99G>T | Intron (SNP) | VAF 237/588 reads (40%) | called by muse, mutect2, varscan2
- UBE3B | c.713+68C>A | Intron (SNP) | VAF 138/755 reads (18%) | called by muse, mutect2, varscan2
